Surgical pathology report (de-identified scan), TCGA case TCGA-KP-A3W1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site British Columbia Cancer Agency, specimen TCGA-KP-A3W1-01A (Primary Tumor).

[page 1 of 2]
Anatomical Pathology

Case:

MRN:

PHN:

Ordering Physician:

Final Diagnosis:

- A. Left pelvic lymph nodes: Three benign lymph nodes, negative for metastasis.
- B. Right pelvic lymph nodes: Two benign lymph nodes, negative for metastasis.
- C. Hysterectomy and bilateral salpingo-oophorectomy specimen:
1. High-grade endometrial serous carcinoma.
2. Figo grade 3/3.
3. Only superficial invasion of inner half of myometrium with least thickness of uninvolved myometrium measuring 1.3 cm.
4. No lymphovascular invasion.
5. Carcinoma extends to lower edge of endometrial cavity but does not involve the endocervix.
6. No extrauterine extension.
7. Non-carcinomatous endometrium showing atrophy.
8. Histologically unremarkable ovaries and fallopian tubes.
9. Pelvic washings: Benign mesothelial cells and chronic inflammatory cells.
10. pT1aN0.

ICD-O3
CARCINOMA, SEROUS, NOS
8441/3
site: endometrium
CSH.1
4-25-12
RD

Clinical History as Provided by Submitting Physician:

year-old female with serous high-grade adeno CA of endometrium

Cytology ~~XXXXXX~~

Gross Description:

Received are three containers, each labelled with the patient's name, XXXXXXXXXXXX, and demographics.

Container A is labelled, LEFT PELVIC NODE, and consists of an adipose tissue fragment measuring 4.6 x 1.8 x 1.5 cm. Five lymph nodes are identified on dissection. These lymph nodes are submitted in toto as follows:

- A1-A2 - one lymph node (in four segments)
A3 - two lymph nodes
A4 - two lymph nodes

Container B is labelled, RIGHT PELVIC NODE, and consists of an adipose tissue fragment measuring 3.7 x 2.2 x 1.2 cm. Three lymph nodes are identified on dissection. These lymph nodes are submitted in toto as follows:

- B1-B2 - one lymph node (in four segments)
B3 - two lymph nodes

Container C is labelled, UTERUS, OVARIES AND CERVIX, and consists of a hysterectomy and bilateral salpingo-oophorectomy specimen.

[page 2 of 2]
The specimen weighs 122.4 g. The uterus measures 8.5 x 6 x 3.8 cm. The serosal surface is tan and dull. The cervix is grossly unremarkable.

The right ovary measures 2 x 1.2 x 0.8 cm and the attached right fimbriated fallopian tube measures 6 cm in length x 0.7 cm in diameter. The left ovary measures 2.3 x 1.3 x 0.7 cm and the attached left fimbriated fallopian tube measures 5 cm in length x 1 cm in diameter. Both ovaries and fallopian tubes are grossly unremarkable.

On opening the uterine corpus, the endometrium is involved by tumor, 4.5 cm in greatest dimension, involving both the anterior and posterior aspects but mainly the anterior aspect of the endometrium. The tumor does appear to invade the myometrium to the depth of 0.5 cm (1.3 cm from the surface of the uterus). The myometrium measures up to 0.6 cm in thickness, with no evidence of myomatous nodules. A sample from the tumor is taken for

Representative sections are submitted as follows:

- C1 - right fallopian tube fimbria
- C2 - right ovary
- C3 - left fallopian tube fimbria
- C4 - left ovary
- C5 - anterior cervix
- C6 - posterior cervix
- C7 - posterior cul-de-sac
- C8 - anterior LUS
- C9 - posterior LUS
- C10-C14 - endometrial tumor from the anterior wall to show greatest depth of invasion
- C15-C20 - endometrial tumor from the posterior wall to show greatest depth of invasion

The remainder of the specimen is saved.

Source: NCI Genomic Data Commons file 863c369d-f81d-440f-b883-6905800f5425 (TCGA-KP-A3W1.58145248-B111-463A-A1CC-32DA993F0B26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).